Somatic mutation profile of tumor specimen TARGET-30-PAILNU-01A (aliquot TARGET-30-PAILNU-01A-01W) from TARGET case TARGET-30-PAILNU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 4.6 years (1,683 days).
Specimen TARGET-30-PAILNU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7837eda-e103-48f2-b462-f905655f831e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAILNU-10A (Blood Derived Normal), aliquot TARGET-30-PAILNU-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/318b42f4-39e2-416e-ab5f-0005d6d18443

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Nonsense Mutation 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IVD | c.1240C>T p.R414W (on ENST00000651168; = p.R411W on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237032588, CM149150, COSV51100066; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2477C>A p.P826Q | Missense Mutation (SNP) | VAF 71/122 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60357979, COSV60363489; called by muse, mutect2, varscan2
- CPA6 | c.448C>G p.H150D | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs146673015; called by muse, mutect2
- DNAH10 | c.10348C>A p.L3450M (on ENST00000409039; = p.L3389M on NM_207437.3) | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as COSV68997461; called by muse, mutect2, varscan2
- DSG1 | c.250A>T p.T84S | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs774601712, COSV57137558; called by muse, mutect2, varscan2
- ELMO1 | c.1208G>A p.S403N | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60314163; called by muse, mutect2, varscan2
- F13B | c.1435G>T p.G479* | Nonsense Mutation (SNP) | VAF 30/188 reads (16%) | catalogued as COSV66374853, COSV66375965; called by muse, mutect2, varscan2
- KCTD3 | c.1058A>C p.D353A | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52068755; called by muse, mutect2, varscan2
- KLHL5 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV54676888; called by muse, mutect2, varscan2
- OR10H2 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 89/638 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV100008627, COSV59946548; called by muse, mutect2, varscan2
- OR8D2 | c.350C>G p.A117G | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV62488727, COSV62488776; called by muse, mutect2, varscan2
- PTPN13 | c.2431G>T p.V811L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as COSV57412255; called by muse, mutect2, varscan2
- RAPGEF5 | c.387G>T p.K129N (on ENST00000401957 / NM_001367602.2; = p.K432N on NM_012294.5) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV59787705; called by muse, mutect2, varscan2
- SPHKAP | c.2083A>C p.N695H | Missense Mutation (SNP) | VAF 95/490 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV60871704; called by muse, mutect2, varscan2
- TRABD2A | c.1257C>A p.F419L (on ENST00000409520 / NM_001277053.2; = p.F370L on NM_001080824.3) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52872284; called by muse, mutect2, varscan2
- ZNF311 | c.699A>T p.K233N | Missense Mutation (SNP) | VAF 62/308 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV65853242; called by muse, mutect2, varscan2
- ZWINT | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV59186033; called by muse, mutect2, varscan2
- CLCN4 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 42/564 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- L3MBTL4 | c.1307C>A p.S436* | Nonsense Mutation (SNP) | VAF 21/438 reads (5%) | called by muse, mutect2
- GCNT2 | c.1011C>T p.G337= (on ENST00000379597 / NM_001374747.1; = p.G335= on NM_001491.3) | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as COSV53943354; called by muse, mutect2, varscan2
- MC2R | c.57C>T p.S19= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs370021107, COSV59619312; called by muse, mutect2, varscan2
- SPRR2A | c.132C>A p.P44= | Silent (SNP) | VAF 184/826 reads (22%) | catalogued as COSV66991428; called by muse, mutect2, varscan2
- TAX1BP1 | c.969C>A p.G323= | Silent (SNP) | VAF 33/194 reads (17%) | catalogued as COSV55295059; called by muse, mutect2, varscan2
- SNORD116-7 | n.1G>T | RNA (SNP) | VAF 28/173 reads (16%) | called by muse, mutect2, varscan2
- SPATA13 | c.290-5317G>A | Intron (SNP) | VAF 28/119 reads (24%) | catalogued as rs1429690837; called by muse, mutect2, varscan2
